CGCI case BLGSP-71-19-00102 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f982e6e-e728-424e-9f55-9918e5532538

Demographics
Sex at birth: male; Race: white; Age at index: 6 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 6.2 years (2,276 days); Year of diagnosis: 1984; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 11,047 days (30.2 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Liver; Sites of involvement: Bone, NOS / Liver.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes tested: 1; Tumor largest dimension diameter: 6 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 11,047 days (30.2 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 357 [Blood test normal range upper: 300].

Other clinical attributes
- Day 0: Weight: 20 kg; Height: 116 cm; BMI: 14.9.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00102-01A-02-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-19-00102-01A-02-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-19-00102-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: malignant lymphoma, undifferentiated, burkitt's type; Extranodal site involvement: 2; Lymph nodes examined: Yes; Other pos node location: rt. cervical.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 357.
